Somatic mutation profile of tumor specimen 0DNCOO from CCDI case PBBZSX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,272 days).
Specimen 0DNCOO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8320b41b-d298-4f11-b25f-98a8e6dd7b33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCGW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2dd6a00-c6d3-42ed-a149-a1361d666fdc

The open-access MAF lists 547 somatic variants for this specimen: 341 protein-altering or splice-affecting, 136 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 136, Intron 41, 3'UTR 18, Nonsense Mutation 17, Splice Region 7, 5'UTR 7, RNA 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NFIA | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 160/376 reads (43%) | catalogued as rs1553149185; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 186/404 reads (46%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 100/187 reads (53%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 148/347 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- ABCC3 | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs547523159; called by muse, varscan2
- AC023055.1 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 214/450 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.742); catalogued as rs183066383; called by muse, varscan2
- ACTL7A | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs141606404; called by muse, varscan2
- ADAMTS9 | c.3670A>G p.T1224A | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs150229587; called by muse, varscan2
- AGL | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370787356; ClinVar: uncertain significance; called by muse, varscan2
- AKIRIN2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs944028378, COSV57637866; called by muse, varscan2
- AMOTL1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs773678862; called by muse, varscan2
- AMPH | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 128/306 reads (42%) | catalogued as rs771517892, COSV57739938; called by muse, varscan2
- ANKRD39 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs11556450, COSV101135635, COSV66813182; called by muse, varscan2
- ANXA13 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.167); catalogued as rs1158464506, COSV51626318; called by muse, varscan2
- AP002512.3 | c.1174A>T p.I392F | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs757151273; called by muse, varscan2
- ARHGAP25 | c.1415C>T p.S472L (on ENST00000409202 / NM_001007231.3; = p.S464L on NM_014882.3) | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as rs199776517; called by muse, varscan2
- ARHGAP27 | c.1547G>A p.R516Q (on ENST00000428638 / NM_001282290.1; = p.R175Q on NM_199282.3) | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776297819; called by muse, varscan2
- ARHGEF16 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs775577377; called by muse, varscan2
- ARID2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 145/316 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs896638040, COSV57600821, COSV57606795; called by muse, varscan2
- ARID2 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 73/385 reads (19%) | catalogued as COSV57596882; called by muse, varscan2
- ARL13A | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs756821238, COSV65880061; called by muse, varscan2
- ATP8B4 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 134/144 reads (93%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745355532, COSV52708582; called by muse, varscan2
- ATXN2L | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57365138; called by muse, varscan2
- BAHCC1 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs542530969; called by muse, varscan2
- BAHD1 | c.1604G>A p.C535Y | Missense Mutation (SNP) | VAF 90/100 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421048710; called by muse, varscan2
- BBS2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs376883866; called by muse, varscan2
- BCL2L11 | c.316G>A p.A106T (on ENST00000393256 / NM_138621.5; = p.A46T on NM_006538.5) | Missense Mutation (SNP) | VAF 148/312 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV58029964; called by muse, varscan2
- BMP10 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383424438; called by muse, varscan2
- C1orf100 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 182/208 reads (88%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs762477027, COSV57374505; called by muse, varscan2
- C1orf159 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs369711809; called by muse, varscan2
- CACNA1H | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047092055; called by muse, varscan2
- CACNA2D2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs201610016, COSV56561218; ClinVar: uncertain significance; called by muse, varscan2
- CAND1 | c.2383T>C p.S795P | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1404893908; called by muse, varscan2
- CAPN15 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs748950993; called by muse, varscan2
- CARMIL2 | c.2185-7G>A | Splice Region (SNP) | VAF 48/110 reads (44%) | catalogued as rs371241229; called by muse, varscan2
- CCDC154 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs572066006; called by muse, varscan2
- CD300A | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as rs750498629; called by muse, varscan2
- CDC23 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1474468294; called by muse, varscan2
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, varscan2
- CDK5RAP3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs922381767, COSV58114345; called by muse, varscan2
- CEACAM6 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs187864306, COSV52268286; called by muse, varscan2
- CERS5 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 76/313 reads (24%) | catalogued as rs751147994, COSV58189378; called by muse, varscan2
- CHFR | c.1582G>A p.G528S (on ENST00000432561 / NM_001161345.1; = p.G487S on NM_018223.2) | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1448818469; called by muse, varscan2
- CHRDL1 | c.1279C>T p.R427C (on ENST00000372045; = p.R433C on NM_145234.4) | Missense Mutation (SNP) | VAF 200/408 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54329346, COSV99028703; called by muse, varscan2
- CLMN | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 154/368 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766194456; called by muse, varscan2
- CNNM3 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as rs147307623; called by muse, varscan2
- CNTRL | c.5588G>A p.R1863Q | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs376534663, COSV53043451; called by muse, varscan2
- COG3 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs141105698; called by muse, varscan2
- COL6A2 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs775590810, COSV52422955; called by muse, varscan2
- CPO | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs144914072; called by muse, varscan2
- CTIF | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs758267207; called by muse, varscan2
- CTNNA2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs1278915845, COSV63564488; called by muse, varscan2
- CTNND2 | c.2974G>A p.G992S | Missense Mutation (SNP) | VAF 132/312 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.051); catalogued as rs369657251, COSV100481585; called by muse, varscan2
- CTTN | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs145706267; called by muse, varscan2
- CYFIP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 106/129 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1414587779; called by muse, varscan2
- CYP2F1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 121/240 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58529125; called by muse, varscan2
- DAO | c.309G>A p.P103= | Splice Region (SNP) | VAF 127/280 reads (45%) | catalogued as rs147144733; called by muse, varscan2
- DAXX | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455644209, COSV56466568; called by muse, varscan2
- DBN1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs1416082865, COSV99445551; called by muse, varscan2
- DCAKD | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs760851820, COSV100149388; called by muse, varscan2
- DHRS13 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs749371989; called by muse, varscan2
- DHX37 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765519542; called by muse, varscan2
- DIP2C | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 67/349 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1356539941, COSV55151694; called by muse, varscan2
- DMBT1 | c.7442G>A p.R2481H (on ENST00000338354 / NM_001377530.1; = p.R1724H on NM_004406.3) | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs1455738382; called by muse, varscan2
- DNAH1 | c.7709G>A p.R2570H | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750305711; called by muse, varscan2
- DNAH17 | c.5387G>A p.R1796Q | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs752524285, COSV101103294; called by muse, varscan2
- DOHH | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs537473356, COSV51744238; called by muse, varscan2
- DSP | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777763456, COSV101131912, COSV65792008; ClinVar: uncertain significance; called by muse, varscan2
- DTX2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs559156215, COSV56860367, COSV56864609; called by muse, varscan2
- DYNLT1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs979162647, COSV65560123; called by muse, varscan2
- DZIP3 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs144458628; called by muse, varscan2
- ELOA | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 181/394 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs144663226; called by muse, varscan2
- EMILIN1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs760161904; called by muse, varscan2
- EPB41L1 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 141/282 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs371544808; called by muse, varscan2
- ERBB2 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV54068888; called by muse, varscan2
- ERVV-1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); catalogued as COSV101654575; called by muse, varscan2
- FAM120C | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1557129591, COSV60262480; called by muse, varscan2
- FAM83H | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1440698800; called by muse, varscan2
- FCRLA | c.308T>C p.L103P (on ENST00000367959; = p.L80P on NM_032738.4) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358451449; called by muse, varscan2
- FLRT1 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs779400742, COSV55358859; called by muse, varscan2
- FOXK1 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as rs866678847; called by muse, varscan2
- FOXRED2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53401468; called by muse, varscan2
- FPR1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as rs933017940, COSV59050877; called by muse, varscan2
- FZD2 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV100190244; called by muse, varscan2
- GALNT10 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs776871894; called by muse, varscan2
- GBA3 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 125/320 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187359066; called by muse, varscan2
- GEMIN8 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs747399327; called by muse, varscan2
- GHITM | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 140/330 reads (42%) | catalogued as rs1192094975; called by muse, varscan2
- GIPC1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775497867; called by muse, varscan2
- GMNC | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370294362; called by muse, varscan2
- GOLGB1 | c.9211G>A p.D3071N | Missense Mutation (SNP) | VAF 93/488 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs771953268, COSV61465430; called by muse, varscan2
- GPKOW | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 160/314 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1014064837; called by muse, varscan2
- GPR139 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs756813774, COSV58502931; called by muse, varscan2
- GRIK2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as rs148565717; called by muse, varscan2
- GRIK5 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 108/251 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs1025783902, COSV99491129; called by muse, varscan2
- GSDME | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as rs369136012; called by muse, varscan2
- GSN | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 120/409 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1246783224; called by muse, varscan2
- GUCY1A1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 165/557 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as rs748904659, COSV56648752, COSV99638479; called by muse, varscan2
- HADH | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476756305, COSV58848671; called by muse, varscan2
- HDAC9 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1054512034, COSV101286646; called by muse, varscan2
- HEATR5B | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 158/346 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs369680339, COSV51850221; called by muse, varscan2
- HELLS | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 220/440 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53299880; called by muse, varscan2
- HM13 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753680836; called by muse, varscan2
- HMCN1 | c.14345G>A p.R4782H | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758569536, COSV54904411; called by muse, varscan2
- HS3ST2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1029443879, COSV54463649; called by muse, varscan2
- JAM3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1407009125; called by muse, varscan2
- KAZN | c.1852C>T p.L618F | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs1013409114; called by muse, varscan2
- KCNAB2 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368982347; called by muse, varscan2
- KCNJ1 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM095058, COSV60661182; called by muse, varscan2
- KCTD15 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1292961261; called by muse, varscan2
- KDM5C | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 136/281 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV62891247; called by muse, varscan2
- KHNYN | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774390018, COSV52159433; called by muse, varscan2
- KIAA1109 | c.10178G>A p.R3393H | Missense Mutation (SNP) | VAF 372/604 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756367377; called by muse, varscan2
- KIAA1522 | c.1673C>T p.T558M (on ENST00000373480 / NM_001198972.2; = p.T617M on NM_020888.3) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs747383281, COSV53864801; called by muse, varscan2
- KIF13A | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99435206; called by muse, varscan2
- KIF18B | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs746282391, COSV59274435; called by muse, varscan2
- KL | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs143526946; called by muse, varscan2
- KLHL1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1330006696, COSV64773532, COSV64778274; called by muse, varscan2
- KNDC1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs569932237, COSV100464757; called by muse, varscan2
- LAD1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs780570969; called by muse, varscan2
- LHFPL4 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 152/385 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.623); catalogued as rs1324349956; called by muse, varscan2
- LIG1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs368941216; called by muse, varscan2
- LIPE | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1373737553; called by muse, varscan2
- LMTK2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.669); catalogued as rs139179986; called by muse, varscan2
- LPIN2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 131/154 reads (85%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs751024451, COSV99858546; called by muse, varscan2
- LRBA | c.5786G>A p.R1929Q | Missense Mutation (SNP) | VAF 291/482 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747575946, COSV63954755; called by muse, varscan2
- LRFN2 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs566688459; called by muse, varscan2
- LRP3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs571346965; called by muse, varscan2
- LRP3 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs774930417, COSV53505847; called by muse, varscan2
- LRP8 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs77068558; called by muse, varscan2
- LUZP2 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 85/463 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as COSV61207913; called by muse, varscan2
- MACF1 | c.11965C>T p.R3989* (on ENST00000372915; = p.R1922* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 119/262 reads (45%) | catalogued as COSV57108167; called by muse, varscan2
- MAML3 | c.2956G>A p.A986T | Missense Mutation (SNP) | VAF 103/329 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1394515867; called by muse, varscan2
- MBNL1 | c.1054G>A p.A352T (on ENST00000282486 / NM_207293.2; = p.A346T on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs773149172, COSV56834135; called by muse, varscan2
- MCM6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765220170, COSV51469449; called by muse, varscan2
- MED1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 148/317 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs764084373; called by muse, varscan2
- MEF2A | c.1504G>A p.A502T (on ENST00000557942 / NM_001319206.2; = p.A496T on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs768102176; called by muse, varscan2
- MGP | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 190/428 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200340021, COSV57454442; called by muse, varscan2
- MN1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV56556929; called by muse, varscan2
- MRC1 | c.1811G>T p.R604I | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as rs1554841506; called by muse, varscan2
- MRPL1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 124/446 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1328292633, COSV59677321; called by muse, varscan2
- MSTO1 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 142/294 reads (48%) | catalogued as rs1362800658; called by muse, varscan2
- MTCH1 | c.759C>T p.F253= | Splice Region (SNP) | VAF 121/278 reads (44%) | catalogued as rs369542410; called by muse, varscan2
- MTHFD1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as rs4902283, COSV99386977; called by muse, varscan2
- MTM1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 86/392 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV60337394; called by muse, varscan2
- MYO5C | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 176/195 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1017902309; called by muse, varscan2
- MYOM3 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs779278585; called by muse, varscan2
- NCBP1 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 302/474 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766937640; called by muse, varscan2
- NCOA2 | c.3607C>T p.R1203C | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1355132406, COSV51220555; called by muse, varscan2
- NIBAN1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs542303174, COSV62287892; called by muse, varscan2
- NIFK | c.624+6A>T | Splice Region (SNP) | VAF 132/322 reads (41%) | catalogued as rs541358407; called by muse, varscan2
- NISCH | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 135/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs372082480; called by muse, varscan2
- NLRX1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs575103827, COSV52704757, COSV52710301; called by muse, varscan2
- NOD1 | c.2738C>T p.T913I | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1289618765; called by muse, varscan2
- NR1H2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 137/279 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs764103032; called by muse, varscan2
- NR5A1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774216266, CM137541; called by muse, varscan2
- NRBP1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758609544, COSV51993968; called by muse, varscan2
- NUP210 | c.5366G>A p.R1789H | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1334674684; called by muse, varscan2
- NWD2 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs868075044; called by muse, varscan2
- NXPE3 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs768091800; called by muse, varscan2
- OBSL1 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767381211, COSV54723064; called by muse, varscan2
- PAK5 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760330867, COSV62035809; called by muse, varscan2
- PALD1 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs780067595, COSV99697850; called by muse, varscan2
- PCDHA12 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.945); catalogued as rs1554168317, COSV56560353; called by muse, varscan2
- PCDHA8 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65332452; called by muse, varscan2
- PCDHGB6 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV53991608; called by muse, varscan2
- PDGFRA | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57264810; called by muse, varscan2
- PDXDC1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs141392697, COSV55073666; called by muse, varscan2
- PEX1 | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 121/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138008298; called by muse, varscan2
- PHLDB2 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1301070338, COSV67316478; called by muse, varscan2
- PKP4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs201152077, COSV67679055, COSV67679395; called by muse, varscan2
- PLEKHF1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs975944364; called by muse, varscan2
- PLXNA1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as rs1347349953, COSV99302111; called by muse, varscan2
- PLXND1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 118/205 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs781053507, COSV60714467; called by muse, varscan2
- PLXND1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768351629; called by muse, varscan2
- PNMA2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV72908469; called by muse, varscan2
- PNPLA6 | c.664G>A p.V222I (on ENST00000414982 / NM_001166111.2; = p.V174I on NM_006702.5) | Missense Mutation (SNP) | VAF 132/282 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs1018645754; called by muse, varscan2
- PPP1CA | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 121/259 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as rs759797722; called by muse, varscan2
- PPP1R12A | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 184/386 reads (48%) | catalogued as COSV99700389; called by muse, varscan2
- PRDM14 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 192/402 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1036596459, COSV52572507; called by muse, varscan2
- PRDM15 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs764627146; called by muse, varscan2
- PSMA1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs776935096, COSV67165668; called by muse, varscan2
- PTPRJ | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69252141; called by muse, varscan2
- RANGAP1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 208/426 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs761229217; called by muse, varscan2
- RAPSN | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs751845474, COSV54085212; called by muse, varscan2
- RASSF5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs782638829; called by muse, varscan2
- RCBTB1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs374135653, COSV51638333; called by muse, varscan2
- RFTN1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775324927, COSV100490010, COSV61918145; called by muse, varscan2
- RGS18 | c.450G>A p.E150= | Splice Region (SNP) | VAF 28/165 reads (17%) | catalogued as rs764761352; called by muse, varscan2
- RHBDF2 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs779759809, COSV51684941; called by muse, varscan2
- SALL2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.355); catalogued as rs376577664; called by muse, varscan2
- SCARA3 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs371434171, COSV57270690; called by muse, varscan2
- SCGN | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 174/367 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1419654916, COSV58546939; called by muse, varscan2
- SCN1B | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as rs778461222, COSV99386626; ClinVar: uncertain significance; called by muse, varscan2
- SEC16A | c.6874C>T p.R2292C | Missense Mutation (SNP) | VAF 215/368 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529911977; called by muse, varscan2
- SEMA6A | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 89/191 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs367927704; called by muse, varscan2
- SEPTIN12 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247964300; called by muse, varscan2
- SH3RF2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 135/278 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs771899314; called by muse, varscan2
- SHISA5 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs140407949; called by muse, varscan2
- SHROOM2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1425621471, COSV101098081; called by muse, varscan2
- SLC12A3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200697179, CM014404, CM993210, COSV52635909; called by muse, varscan2
- SLC12A9 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs374398396; called by muse, varscan2
- SLC16A2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs1197846957, COSV52089185; called by muse, varscan2
- SLC25A25 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs751749247, COSV66086157; called by muse, varscan2
- SLC25A4 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1468212457; called by muse, varscan2
- SLC27A1 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs763436997; called by muse, varscan2
- SLC29A3 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV104427493; called by muse, varscan2
- SLC35E2B | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756610571, COSV99327332; called by muse, varscan2
- SLC66A1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 113/250 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as rs773086016, COSV64320501; called by muse, varscan2
- SLC7A1 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 145/294 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548607156, COSV66330325; called by muse, varscan2
- SLC7A1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as rs200608225; called by muse, varscan2
- SLC9A7 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60378341; called by muse, varscan2
- SMAD6 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs1471656357, COSV99993966; called by muse, varscan2
- SORBS1 | c.1609G>A p.E537K (on ENST00000361941 / NM_001034954.2; = p.E327K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs200192581, COSV53352982; called by muse, varscan2
- SORL1 | c.2650G>A p.V884M | Missense Mutation (SNP) | VAF 131/309 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs138761977, CM164112; called by muse, varscan2
- SPIRE2 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370409614; called by muse, varscan2
- SPON1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 134/260 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868975738, COSV59964255; called by muse, varscan2
- STAB2 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs776338745, COSV66345984; called by muse, varscan2
- STRADB | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs191184636; called by muse, varscan2
- STT3B | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs759628570, COSV55506119; called by muse, varscan2
- SUPT20HL2 | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs397832843; called by muse, varscan2
- SYNE1 | c.23258G>A p.R7753H (on ENST00000367255 / NM_182961.4; = p.R7682H on NM_033071.3) | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779568455, COSV55038859; ClinVar: uncertain significance; called by muse, varscan2
- SYNM | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 99/382 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs782799108; called by muse, varscan2
- TBKBP1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs756835766; called by muse, varscan2
- TCTE1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs138607076; called by muse, varscan2
- TCTN2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs376996387; ClinVar: uncertain significance; called by muse, varscan2
- TGFBR3 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201034517, COSV53021339; called by muse, varscan2
- TGM6 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs751732632, COSV52478754; called by muse, varscan2
- THAP5 | c.961G>A p.E321K (on ENST00000415914 / NM_001130475.3; = p.E279K on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 223/452 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs370107035; called by muse, varscan2
- TLR2 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 154/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552749059, COSV52607388, COSV52607453; called by muse, varscan2
- TMEM151B | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs1203871431; called by muse, varscan2
- TMEM62 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 152/165 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs376300591, COSV99543668; called by muse, varscan2
- TNN | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 189/361 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs199923075; called by muse, varscan2
- TRAPPC12 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368315810, COSV60849998; called by muse, varscan2
- TRHDE | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 160/382 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs367558141, COSV99672037; called by muse, varscan2
- TRIM71 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as rs764224606; called by muse, varscan2
- TRPM8 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs148556306; called by muse, varscan2
- TTYH1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373169284; called by muse, varscan2
- TUBB8 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV59116973; called by muse, varscan2
- UBA1 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 195/381 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60114511; called by muse, varscan2
- UCN2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371104367; called by muse, varscan2
- UNC5C | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763344659, COSV101497886; called by muse, varscan2
- UQCRC2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 173/367 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as rs755080798; called by muse, varscan2
- USP39 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs1208978885, COSV60383956; called by muse, varscan2
- VPS52 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 183/397 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768171623, COSV101460402; called by muse, varscan2
- VWA5B1 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs764856363, COSV99233868; called by muse, varscan2
- WDR90 | c.4057C>T p.R1353* | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as rs374521595; called by muse, varscan2
- WHRN | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54335900; called by muse, varscan2
- WWC1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 162/343 reads (47%) | catalogued as COSV54651748; called by muse, varscan2
- XRRA1 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs148718535; called by muse, varscan2
- YLPM1 | c.4096C>T p.R1366C | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs367980660; called by muse, varscan2
- ZC3H12D | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs779864351, COSV66323732; called by muse, varscan2
- ZFP82 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.266); catalogued as rs1437761313; called by muse, varscan2
- ZFP92 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1176360219; called by muse, varscan2
- ZMYND10 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747944767; ClinVar: uncertain significance; called by muse, varscan2
- ZNF366 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.163); catalogued as COSV59218809; called by muse, varscan2
- ZNF519 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 124/317 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101645556; called by muse, varscan2
- ZNF521 | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 170/340 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs752693444, COSV64126391, COSV64130598; called by muse, varscan2
- ZNF704 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs139476385; called by muse, varscan2
- ZNFX1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776308981; called by muse, varscan2
- ADAMTS14 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, varscan2
- ASMTL | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, varscan2
- BAZ1A | c.1805G>T p.S602I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, varscan2
- BCL11A | c.2021G>A p.G674E (on ENST00000335712 / NM_001365609.1; = p.G708E on NM_018014.4) | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, varscan2
- BNC1 | c.2892C>A p.N964K | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, varscan2
- C15orf61 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, varscan2
- CACTIN | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CC2D1A | c.2660G>T p.S887I | Missense Mutation (SNP) | VAF 129/297 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.059); called by muse, varscan2
- CHD2 | c.4801C>A p.L1601I | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, varscan2
- CHRNE | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- CHSY3 | c.2519C>A p.P840H | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, varscan2
- CNTNAP1 | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, varscan2
- COL5A3 | c.3919G>C p.G1307R | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CREG2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, varscan2
- CYLC1 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 120/285 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, varscan2
- DDOST | c.923T>C p.V308A (on ENST00000415136; = p.V291A on NM_005216.5) | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, varscan2
- DHX8 | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- DOCK11 | c.5461G>A p.V1821I | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.094); called by muse, varscan2
- DPP8 | c.1570C>T p.R524W (on ENST00000341861 / NM_001320875.2; = p.R508W on NM_017743.6) | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- ELP2 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, varscan2
- FAM155B | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, varscan2
- FAM184A | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); called by muse, varscan2
- FANCI | c.2582G>C p.G861A | Missense Mutation (SNP) | VAF 187/377 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, varscan2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, varscan2
- FMR1 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | called by muse, varscan2
- GALNT5 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.251); called by muse, varscan2
- GEMIN8 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, varscan2
- GRM5 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 130/298 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- HECA | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, varscan2
- HLA-DQA1 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 213/380 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- HTR2A | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 136/314 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); called by muse, varscan2
- IL12RB1 | c.124+8G>A | Splice Region (SNP) | VAF 36/180 reads (20%) | called by muse, varscan2
- IL17RA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, varscan2
- IPO8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ISG20 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KBTBD12 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 198/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- KHDRBS2 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 104/242 reads (43%) | called by muse, varscan2
- LDHAL6A | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- LEMD3 | c.1036T>C p.C346R | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, varscan2
- LRP1B | c.10465A>G p.I3489V | Missense Mutation (SNP) | VAF 151/340 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, varscan2
- LRRC4B | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, varscan2
- LRRC57 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 146/170 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MAGEB3 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, varscan2
- MCM3 | c.986G>A p.C329Y (on ENST00000229854 / NM_001366374.2; = p.C319Y on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, varscan2
- MFAP2 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MRPL46 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, varscan2
- NAV2 | c.1454C>T p.A485V (on ENST00000396087 / NM_001244963.2; = p.A462V on NM_145117.5) | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- NDUFS6 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 146/352 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, varscan2
- NRP2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 162/390 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- NTNG2 | c.1223-6G>A | Splice Region (SNP) | VAF 12/84 reads (14%) | called by muse, varscan2
- PAN2 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, varscan2
- PIP5K1B | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- PITRM1 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, varscan2
- PLAGL1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLPPR2 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, varscan2
- RABEP1 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, varscan2
- RHOV | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 108/134 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, varscan2
- RNF128 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- RNF31 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.994); called by muse, varscan2
- RUNDC3A | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, varscan2
- SCN2A | c.3017C>A p.A1006D | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, varscan2
- SECISBP2 | c.487A>G p.R163G | Missense Mutation (SNP) | VAF 157/488 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- SETD2 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 151/301 reads (50%) | called by muse, varscan2
- SLC9A5 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- SLC9A5 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); called by muse, varscan2
- SLMAP | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 186/357 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SMG1 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 192/437 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- SPATA31A6 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 70/439 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, varscan2
- STAT5B | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 165/363 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- SYAP1 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.462); called by muse, varscan2
- TACC2 | c.7402G>A p.A2468T (on ENST00000334433; = p.A546T on NM_006997.4) | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TFRC | c.1135A>G p.N379D | Missense Mutation (SNP) | VAF 230/448 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TRAF6 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 164/340 reads (48%) | called by muse, varscan2
- TRAPPC12 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); called by muse, varscan2
- TRMT1 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 26/165 reads (16%) | called by muse, varscan2
- TUBB4B | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, varscan2
- TXNRD3 | c.1525A>T p.I509L (on ENST00000523403 / NM_001173513.2; = p.I545L on NM_052883.2) | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, varscan2
- WDFY3 | c.9313T>G p.W3105G | Missense Mutation (SNP) | VAF 133/482 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- ZFAND1 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- ZNF148 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 180/370 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); called by muse, varscan2
- ABCA2 | c.2988C>A p.A996= (on ENST00000614293; = p.A966= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 155/220 reads (70%) | called by muse, varscan2
- ABCA2 | c.1230C>T p.N410= (on ENST00000614293; = p.N380= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs546613988; called by muse, varscan2
- ACAA1 | c.288C>T p.A96= | Silent (SNP) | VAF 146/304 reads (48%) | catalogued as rs148457692; called by muse, varscan2
- ACSL1 | c.219C>T p.S73= | Silent (SNP) | VAF 320/510 reads (63%) | catalogued as rs139053741, COSV55664976; called by muse, varscan2
- ADAMTS7 | c.4668G>A p.A1556= | Silent (SNP) | VAF 110/304 reads (36%) | catalogued as rs770819174; called by muse, varscan2
- ADD1 | c.1371C>T p.S457= | Silent (SNP) | VAF 135/318 reads (42%) | catalogued as rs752567249; called by muse, varscan2
- ADGRL1 | c.2583G>A p.S861= (on ENST00000340736 / NM_001008701.3; = p.S856= on NM_014921.5) | Silent (SNP) | VAF 102/229 reads (45%) | catalogued as rs375578685; called by muse, varscan2
- AL592490.1 | c.855G>A p.Q285= | Silent (SNP) | VAF 73/145 reads (50%) | called by muse, varscan2
- ANKRD24 | c.3114C>A p.R1038= | Silent (SNP) | VAF 42/328 reads (13%) | called by muse, varscan2
- ANKRD6 | c.759G>A p.P253= | Silent (SNP) | VAF 144/314 reads (46%) | catalogued as rs779843875; called by muse, varscan2
- ANKS1B | c.2844C>T p.H948= (on ENST00000547776 / NM_152788.4; = p.H174= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/321 reads (22%) | catalogued as rs374794796; called by muse, varscan2
- AP2A2 | c.1020C>T p.R340= | Silent (SNP) | VAF 128/266 reads (48%) | catalogued as rs747326791; called by muse, varscan2
- ARHGAP24 | c.2142A>G p.R714= (on ENST00000395184 / NM_001025616.3; = p.R621= on NM_031305.3) | Silent (SNP) | VAF 240/748 reads (32%) | called by muse, varscan2
- ARHGAP35 | c.4239C>T p.D1413= | Silent (SNP) | VAF 88/211 reads (42%) | catalogued as rs749058550, COSV101350733; called by muse, varscan2
- AS3MT | c.114G>A p.P38= | Silent (SNP) | VAF 58/326 reads (18%) | called by muse, varscan2
- ATG2A | c.1635G>A p.T545= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as rs202089842; called by muse, varscan2
- ATP5MGL | c.228C>T p.N76= | Silent (SNP) | VAF 87/438 reads (20%) | catalogued as rs781619084, COSV61544657; called by muse, varscan2
- BCL2L13 | c.1200C>T p.P400= | Silent (SNP) | VAF 122/262 reads (47%) | catalogued as rs374385339; called by muse, varscan2
- BPIFB3 | c.231C>T p.G77= | Silent (SNP) | VAF 130/297 reads (44%) | catalogued as COSV64958239; called by muse, varscan2
- CAMSAP1 | c.3315G>A p.A1105= | Silent (SNP) | VAF 90/250 reads (36%) | catalogued as rs895709302, COSV100410438; called by muse, varscan2
- CASKIN1 | c.2517C>T p.P839= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs541957148; called by muse, varscan2
- CCDC130 | c.717C>T p.Y239= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs766112312; called by muse, varscan2
- CEACAM20 | c.447C>T p.S149= | Silent (SNP) | VAF 102/221 reads (46%) | catalogued as rs562062188; called by muse, varscan2
- CELSR3 | c.7953C>T p.G2651= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as rs760257509, COSV50855210; called by muse, varscan2
- CFHR4 | c.783A>G p.P261= (on ENST00000367416 / NM_001201551.2; = p.P262= on NM_001201550.3) | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as COSV99260103; called by muse, varscan2
- CHGA | c.123C>T p.S41= | Silent (SNP) | VAF 162/378 reads (43%) | catalogued as rs769428586; called by muse, varscan2
- CLIP3 | c.870C>T p.S290= | Silent (SNP) | VAF 104/244 reads (43%) | catalogued as rs368037147, COSV100859306; called by muse, varscan2
- COL7A1 | c.5385G>A p.P1795= | Silent (SNP) | VAF 90/186 reads (48%) | catalogued as rs780121797, COSV60397563; called by muse, varscan2
- CORO1B | c.597C>T p.S199= | Silent (SNP) | VAF 100/244 reads (41%) | catalogued as rs771850944; called by muse, varscan2
- CS | c.618C>T p.I206= | Silent (SNP) | VAF 169/368 reads (46%) | catalogued as rs1434408528, COSV100673225, COSV60832106; called by muse, varscan2
- CTIF | c.1663C>T p.L555= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, varscan2
- CTRL | c.108C>T p.N36= | Silent (SNP) | VAF 108/252 reads (43%) | catalogued as rs146079104; ClinVar: likely benign; called by muse, varscan2
- CYP2D6 | c.552C>T p.N184= | Silent (SNP) | VAF 60/420 reads (14%) | catalogued as rs759756045; called by muse, varscan2
- DCAF12L1 | c.96C>T p.D32= | Silent (SNP) | VAF 94/178 reads (53%) | catalogued as rs1186246698, COSV64421377; called by muse, varscan2
- DDX51 | c.1923G>A p.P641= | Silent (SNP) | VAF 112/252 reads (44%) | catalogued as rs776409529, COSV57958949; called by muse, varscan2
- DMPK | c.1158G>A p.S386= | Silent (SNP) | VAF 76/150 reads (51%) | catalogued as rs376774997, COSV99353370; called by muse, varscan2
- DNAH17 | c.8664C>T p.D2888= | Silent (SNP) | VAF 100/219 reads (46%) | catalogued as rs61741555; called by muse, varscan2
- DNHD1 | c.13089G>A p.T4363= | Silent (SNP) | VAF 112/259 reads (43%) | catalogued as rs1338296366; called by muse, varscan2
- DOLK | c.1104G>A p.A368= | Silent (SNP) | VAF 108/356 reads (30%) | catalogued as rs765151256, COSV58281353; called by muse, varscan2
- DPH5 | c.249T>C p.G83= | Silent (SNP) | VAF 138/306 reads (45%) | called by muse, varscan2
- DPYSL5 | c.756G>A p.S252= | Silent (SNP) | VAF 135/291 reads (46%) | catalogued as rs189492736; called by muse, varscan2
- DVL3 | c.1542C>T p.G514= | Silent (SNP) | VAF 108/232 reads (47%) | catalogued as rs781638795; called by muse, varscan2
- EIF4B | c.882C>T p.G294= | Silent (SNP) | VAF 48/291 reads (16%) | catalogued as rs540767038, COSV100016691; called by muse, varscan2
- EPS8 | c.657G>A p.A219= | Silent (SNP) | VAF 135/312 reads (43%) | catalogued as rs772702022; called by muse, varscan2
- EXOSC5 | c.312G>A p.A104= | Silent (SNP) | VAF 106/223 reads (48%) | catalogued as rs550529092; called by muse, varscan2
- FAM234A | c.621G>A p.A207= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as rs771266398; called by muse, varscan2
- FASN | c.4254C>T p.D1418= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as rs763488231; called by muse, varscan2
- FES | c.837G>A p.T279= | Silent (SNP) | VAF 113/230 reads (49%) | catalogued as rs2856846; called by muse, varscan2
- FEZ2 | c.327G>A p.S109= | Silent (SNP) | VAF 75/383 reads (20%) | catalogued as rs369406907; called by muse, varscan2
- FKBP8 | c.246C>T p.P82= | Silent (SNP) | VAF 101/223 reads (45%) | catalogued as rs1249901883; called by muse, varscan2
- FLNC | c.7422C>T p.G2474= | Silent (SNP) | VAF 137/267 reads (51%) | catalogued as rs755019331, COSV57950427; called by muse, varscan2
- FRMD6 | c.738G>A p.S246= (on ENST00000344768 / NM_001267046.2; = p.S238= on NM_152330.4) | Silent (SNP) | VAF 52/280 reads (19%) | catalogued as rs769310184, COSV61086359; called by muse, varscan2
- FRY | c.4131G>A p.P1377= | Silent (SNP) | VAF 93/235 reads (40%) | catalogued as rs757832154, COSV66565750; called by muse, varscan2
- GALNT10 | c.534C>T p.A178= | Silent (SNP) | VAF 152/371 reads (41%) | catalogued as rs765829806, COSV99769630; called by muse, varscan2
- GCN1 | c.6027G>A p.T2009= | Silent (SNP) | VAF 85/368 reads (23%) | catalogued as rs759881390; called by muse, varscan2
- GGT1 | c.1185C>T p.S395= | Silent (SNP) | VAF 56/580 reads (10%) | catalogued as rs759573748; called by muse, varscan2
- GLDC | c.2673C>T p.H891= | Silent (SNP) | VAF 94/104 reads (90%) | catalogued as rs144939090, COSV58680418; called by muse, varscan2
- GP1BB | c.585G>A p.P195= | Silent (SNP) | VAF 76/157 reads (48%) | called by muse, varscan2
- GPR61 | c.396G>A p.S132= | Silent (SNP) | VAF 118/284 reads (42%) | catalogued as rs747436555, COSV68177797; called by muse, varscan2
- GPR87 | c.81C>T p.S27= | Silent (SNP) | VAF 175/358 reads (49%) | catalogued as rs756817481, COSV99608825; called by muse, varscan2
- GRIN2C | c.1245C>T p.I415= | Silent (SNP) | VAF 106/237 reads (45%) | catalogued as rs768674628, COSV53111599; called by muse, varscan2
- HECW1 | c.4746G>A p.P1582= | Silent (SNP) | VAF 182/432 reads (42%) | catalogued as rs759900337, COSV67837649; called by muse, varscan2
- HMCN2 | c.9912C>T p.A3304= | Silent (SNP) | VAF 112/338 reads (33%) | catalogued as rs1178364915; called by muse, varscan2
- HRG | c.228G>A p.S76= | Silent (SNP) | VAF 134/304 reads (44%) | catalogued as rs1015656776, COSV51649080; called by muse, varscan2
- HS3ST4 | c.390C>T p.S130= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs1346032240; called by muse, varscan2
- INTS1 | c.966G>A p.A322= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as rs375140847; called by muse, varscan2
- JPH3 | c.1644C>T p.R548= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV52469418; called by muse, varscan2
- KATNIP | c.2244C>T p.P748= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs772320459, COSV55193072; ClinVar: likely benign; called by muse, varscan2
- KLHL30 | c.1209G>A p.T403= | Silent (SNP) | VAF 111/219 reads (51%) | catalogued as rs368843555; called by muse, varscan2
- LAMB4 | c.3636C>A p.V1212= | Silent (SNP) | VAF 174/351 reads (50%) | called by muse, varscan2
- LUZP1 | c.1371C>A p.P457= | Silent (SNP) | VAF 44/227 reads (19%) | called by muse, varscan2
- MAGEB1 | c.300T>C p.T100= | Silent (SNP) | VAF 53/282 reads (19%) | catalogued as rs1270524658; called by muse, varscan2
- MARF1 | c.852C>T p.I284= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as rs1309264920, COSV100706028; called by muse, varscan2
- MROH2A | c.4158G>A p.P1386= | Silent (SNP) | VAF 126/258 reads (49%) | catalogued as rs199594486; called by muse, varscan2
- MSH4 | c.837T>C p.V279= | Silent (SNP) | VAF 142/298 reads (48%) | called by muse, varscan2
- MTMR1 | c.1332A>T p.R444= | Silent (SNP) | VAF 118/300 reads (39%) | called by muse, varscan2
- MYO15A | c.1938G>A p.A646= | Silent (SNP) | VAF 30/67 reads (45%) | called by muse, varscan2
- MYO1E | c.840G>A p.A280= | Silent (SNP) | VAF 158/377 reads (42%) | catalogued as rs910476737; called by muse, varscan2
- MYO7B | c.672C>T p.S224= | Silent (SNP) | VAF 158/352 reads (45%) | catalogued as rs372953123; called by muse, varscan2
- NAA15 | c.1989G>A p.P663= | Silent (SNP) | VAF 278/448 reads (62%) | catalogued as rs931332031; called by muse, varscan2
- NCOA6 | c.3513G>A p.S1171= | Silent (SNP) | VAF 114/228 reads (50%) | catalogued as rs747102209, COSV62868346; called by muse, varscan2
- NFASC | c.465C>T p.G155= (on ENST00000339876 / NM_001378329.1; = p.G149= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 177/369 reads (48%) | catalogued as rs148289271; called by muse, varscan2
- NHEJ1 | c.756A>G p.Q252= | Silent (SNP) | VAF 140/319 reads (44%) | called by muse, varscan2
- NIBAN2 | c.2124C>T p.D708= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as rs1012895792; called by muse, varscan2
- NPR3 | c.93C>T p.G31= | Silent (SNP) | VAF 92/184 reads (50%) | called by muse, varscan2
- ODF2 | c.1371C>T p.D457= (on ENST00000434106 / NM_153433.2; = p.D433= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 160/568 reads (28%) | called by muse, varscan2
- OR52N2 | c.54C>T p.G18= | Silent (SNP) | VAF 133/261 reads (51%) | catalogued as rs372029486; called by muse, varscan2
- PCDH19 | c.309C>T p.L103= | Silent (SNP) | VAF 102/218 reads (47%) | catalogued as COSV55269177; called by muse, varscan2
- PHF20 | c.114C>T p.Y38= | Silent (SNP) | VAF 136/312 reads (44%) | catalogued as rs779477634, COSV59188437; called by muse, varscan2
- PIGT | c.1416C>T p.S472= | Silent (SNP) | VAF 112/310 reads (36%) | catalogued as rs2664565; called by muse, varscan2
- PLCXD1 | c.765G>A p.T255= | Silent (SNP) | VAF 106/229 reads (46%) | catalogued as rs370879507, COSV100397863; called by muse, varscan2
- POLRMT | c.2718C>T p.R906= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as rs749755810, COSV52117801; called by muse, varscan2
- PRDM10 | c.528G>A p.E176= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, varscan2
- PRKACG | c.861C>T p.N287= | Silent (SNP) | VAF 92/356 reads (26%) | catalogued as rs768575040, COSV55250989; called by muse, varscan2
- PRR23A | c.480G>A p.A160= | Silent (SNP) | VAF 100/231 reads (43%) | catalogued as COSV67214619; called by muse, varscan2
- PRSS23 | c.927C>T p.C309= | Silent (SNP) | VAF 109/274 reads (40%) | catalogued as rs922808925; called by muse, varscan2
- PRSS27 | c.798C>T p.T266= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs566068441, COSV57014183; called by muse, varscan2
- PRUNE2 | c.7131C>T p.D2377= | Silent (SNP) | VAF 62/310 reads (20%) | called by muse, varscan2
- PTPRD | c.4692C>T p.I1564= | Silent (SNP) | VAF 106/119 reads (89%) | catalogued as rs138863975; called by muse, varscan2
- RALGDS | c.1902C>T p.S634= | Silent (SNP) | VAF 100/309 reads (32%) | catalogued as rs142280175; called by muse, varscan2
- RBBP4 | c.573G>A p.G191= | Silent (SNP) | VAF 128/317 reads (40%) | catalogued as rs751464384; called by muse, varscan2
- RBMS2 | c.867G>A p.S289= | Silent (SNP) | VAF 122/226 reads (54%) | catalogued as rs61617845; called by muse, varscan2
- RNPS1 | c.579C>T p.P193= | Silent (SNP) | VAF 116/248 reads (47%) | catalogued as rs780026324; called by muse, varscan2
- RRAS2 | c.258C>T p.G86= | Silent (SNP) | VAF 151/330 reads (46%) | catalogued as rs782492074; called by muse, varscan2
- SH3TC1 | c.2094G>A p.S698= | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as rs771910935, COSV55284620; called by muse, varscan2
- SIDT2 | c.645C>T p.N215= | Silent (SNP) | VAF 122/298 reads (41%) | catalogued as rs760782996; called by muse, varscan2
- SLCO3A1 | c.615C>T p.H205= | Silent (SNP) | VAF 84/234 reads (36%) | catalogued as rs987457148, COSV59233257; called by muse, varscan2
- SLX4 | c.2046C>T p.G682= | Silent (SNP) | VAF 120/294 reads (41%) | catalogued as rs762708132; called by muse, varscan2
- SPATC1 | c.153C>T p.S51= | Silent (SNP) | VAF 154/326 reads (47%) | catalogued as rs938450449, COSV66300336; called by muse, varscan2
- SPINDOC | c.201G>A p.P67= | Silent (SNP) | VAF 146/318 reads (46%) | catalogued as rs751270526, COSV53692705; called by muse, varscan2
- SPN | c.1071G>A p.A357= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs914647648; called by muse, varscan2
- SPTBN2 | c.2295C>T p.D765= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as rs140386819; called by muse, varscan2
- SRRM2 | c.6231G>A p.R2077= | Silent (SNP) | VAF 56/236 reads (24%) | catalogued as rs1296830630; called by muse, varscan2
- STAT3 | c.1023C>T p.T341= | Silent (SNP) | VAF 101/200 reads (51%) | catalogued as rs777436789; called by muse, varscan2
- TACC2 | c.6315C>T p.A2105= (on ENST00000334433; = p.A183= on NM_006997.4) | Silent (SNP) | VAF 50/191 reads (26%) | catalogued as rs764129065; called by muse, varscan2
- TACR3 | c.1290G>A p.T430= | Silent (SNP) | VAF 273/429 reads (64%) | catalogued as rs138661164; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TERT | c.1386C>T p.Y462= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs1198114367; called by muse, varscan2
- TEX10 | c.1887G>A p.P629= | Silent (SNP) | VAF 159/567 reads (28%) | catalogued as rs201335996; called by muse, varscan2
- TICAM1 | c.1884G>A p.P628= | Silent (SNP) | VAF 74/150 reads (49%) | catalogued as rs773993340, COSV50229775, COSV99941000; called by muse, varscan2
- TKTL1 | c.885C>T p.C295= | Silent (SNP) | VAF 177/332 reads (53%) | catalogued as rs781785675, COSV54212220; called by muse, varscan2
- TMEM184A | c.843C>T p.C281= | Silent (SNP) | VAF 69/171 reads (40%) | catalogued as rs773322531, COSV52473634; called by muse, varscan2
- TMEM266 | c.897C>T p.A299= | Silent (SNP) | VAF 106/206 reads (51%) | called by muse, varscan2
- TNK2 | c.2127G>A p.A709= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs375607650; called by muse, varscan2
- TOX | c.807G>A p.A269= | Silent (SNP) | VAF 51/339 reads (15%) | catalogued as rs376393252; called by muse, varscan2
- TRPV4 | c.1515G>A p.T505= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs1056692999, COSV99925141; ClinVar: uncertain significance; called by muse, varscan2
- TULP1 | c.1207C>T p.L403= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, varscan2
- UBASH3B | c.1746G>A p.A582= | Silent (SNP) | VAF 191/418 reads (46%) | catalogued as COSV99417727; called by muse, varscan2
- UGCG | c.753A>G p.A251= | Silent (SNP) | VAF 130/439 reads (30%) | called by muse, varscan2
- UMODL1 | c.1380G>A p.A460= | Silent (SNP) | VAF 94/209 reads (45%) | catalogued as rs139481180; called by muse, varscan2
- WFIKKN1 | c.426C>T p.D142= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs757011468; called by muse, varscan2
- ZC3H7B | c.1488C>T p.Y496= | Silent (SNP) | VAF 106/257 reads (41%) | catalogued as rs951145180, COSV60964856; called by muse, varscan2
- ZFP1 | c.1071C>T p.C357= | Silent (SNP) | VAF 108/243 reads (44%) | catalogued as rs1427133066, COSV100182039; called by muse, varscan2
- ZFP69B | c.993T>C p.G331= | Silent (SNP) | VAF 58/266 reads (22%) | catalogued as rs769534623, COSV64316110; called by muse, varscan2
- ZNF469 | c.7146C>T p.A2382= (on ENST00000437464; = p.A2410= on NM_001367624.2) | Silent (SNP) | VAF 78/152 reads (51%) | catalogued as rs1339451382; called by muse, varscan2
- ZNF689 | c.249A>G p.R83= | Silent (SNP) | VAF 45/267 reads (17%) | called by muse, varscan2
- ZZZ3 | c.2403A>G p.L801= | Silent (SNP) | VAF 84/468 reads (18%) | catalogued as rs368073519; called by muse, varscan2
- ACER3 | c.705-61G>A | Intron (SNP) | VAF 74/148 reads (50%) | catalogued as rs373224175; called by muse, varscan2
- ADGRA1 | c.*18G>A | 3'UTR (SNP) | VAF 18/94 reads (19%) | catalogued as rs756592960; called by muse, varscan2
- ADGRB1 | c.1727-14G>A | Intron (SNP) | VAF 72/144 reads (50%) | catalogued as rs1334099552; called by muse, varscan2
- AL136439.1 | chr13:27665990 G>A | 3'Flank (SNP) | VAF 51/101 reads (50%) | catalogued as rs568728057, COSV101294877; called by muse, varscan2
- AL450447.1 | n.1226G>A | RNA (SNP) | VAF 94/267 reads (35%) | called by muse, varscan2
- ANO9 | c.1786+50T>C | Intron (SNP) | VAF 68/122 reads (56%) | called by muse, varscan2
- ANXA1 | c.*28A>T | 3'UTR (SNP) | VAF 86/326 reads (26%) | called by muse, varscan2
- APOBEC3G | c.171+100G>C | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, varscan2
- B3GALNT1 | c.-221+81C>T | Intron (SNP) | VAF 78/144 reads (54%) | called by muse, varscan2
- C4orf33 | c.494+38C>T | Intron (SNP) | VAF 59/184 reads (32%) | catalogued as rs372176189; called by muse, varscan2
- CAPN1 | c.843+81G>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs564968684; called by muse, varscan2
- CCIN | c.-94G>A | 5'UTR (SNP) | VAF 54/187 reads (29%) | catalogued as rs771069177; called by muse, varscan2
- CLPTM1L | c.1532+88C>T | Intron (SNP) | VAF 13/58 reads (22%) | catalogued as rs919326230; called by muse, varscan2
- CNKSR1 | c.392+19C>T | Intron (SNP) | VAF 178/329 reads (54%) | catalogued as rs779116557, COSV64162885; called by muse, varscan2
- CSH2 | c.10+71G>A | Intron (SNP) | VAF 45/100 reads (45%) | catalogued as rs1262324689, COSV61080020; called by muse, varscan2
- DEPDC5 | c.3030+3817C>T | Intron (SNP) | VAF 103/240 reads (43%) | catalogued as rs374223318; called by muse, varscan2
- DHRS2 | c.*14G>A | 3'UTR (SNP) | VAF 102/212 reads (48%) | catalogued as rs142921924; called by muse, varscan2
- DNAJB13 | c.-2C>T | 5'UTR (SNP) | VAF 80/184 reads (43%) | catalogued as rs139276165; called by muse, varscan2
- EGF | c.941-30C>A | Intron (SNP) | VAF 78/498 reads (16%) | called by muse, varscan2
- ELAC2 | c.1660-85C>G | Intron (SNP) | VAF 30/60 reads (50%) | called by muse, varscan2
- ESS2 | c.*27C>T | 3'UTR (SNP) | VAF 70/124 reads (56%) | catalogued as rs756044387, COSV99351338; called by muse, varscan2
- FAR2 | c.190-69G>C | Intron (SNP) | VAF 11/77 reads (14%) | called by muse, varscan2
- FBXO10 | c.2696+25G>A | Intron (SNP) | VAF 148/233 reads (64%) | catalogued as rs767962360, COSV52832178; called by muse, varscan2
- GPNMB | c.-17G>A | 5'UTR (SNP) | VAF 83/182 reads (46%) | catalogued as rs751202578, COSV99326551; called by muse, varscan2
- GTF2A1 | c.*53C>T | 3'UTR (SNP) | VAF 80/161 reads (50%) | catalogued as rs935478672; called by muse, varscan2
- GUCY2C | c.2776+93G>A | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as rs772068248; called by muse, varscan2
- HDAC7 | c.2675-56G>A | Intron (SNP) | VAF 55/106 reads (52%) | catalogued as rs989853495; called by muse, varscan2
- IMMT | c.421+82C>T | Intron (SNP) | VAF 55/120 reads (46%) | catalogued as rs923172262; called by muse, varscan2
- JMJD4 | c.1107+77G>A | Intron (SNP) | VAF 49/60 reads (82%) | catalogued as rs1423638424; called by muse, varscan2
- KCNAB1 | c.275+22449G>A | Intron (SNP) | VAF 142/338 reads (42%) | catalogued as rs370874801; called by muse, varscan2
- KCTD10 | c.217+32C>T | Intron (SNP) | VAF 60/132 reads (45%) | called by muse, varscan2
- KCTD16 | c.*16G>A | 3'UTR (SNP) | VAF 83/196 reads (42%) | catalogued as rs747862089; called by muse, varscan2
- KIF7 | c.3319-97G>A | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs540513085; called by muse, varscan2
- KRT85 | c.-44G>T | 5'UTR (SNP) | VAF 88/152 reads (58%) | catalogued as rs767468180; called by muse, varscan2
- LSM4 | c.*2C>T | 3'UTR (SNP) | VAF 37/104 reads (36%) | catalogued as rs765914833; called by muse, varscan2
- MAPK12 | c.426+12G>A | Intron (SNP) | VAF 83/152 reads (55%) | catalogued as rs775420472; called by muse, varscan2
- MEX3D | c.*221C>T | 3'UTR (SNP) | VAF 34/108 reads (31%) | catalogued as rs748753384, COSV66312471; called by muse, varscan2
- MKRN3 | c.-76G>A | 5'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as rs995302925, COSV100091420; called by muse, varscan2
- MYCBPAP | c.1782+44G>A | Intron (SNP) | VAF 82/162 reads (51%) | catalogued as rs550381936, COSV60410347; called by muse, varscan2
- MYH11 | c.4579-74C>T | Intron (SNP) | VAF 26/44 reads (59%) | catalogued as rs993441604; called by muse, varscan2
- NCSTN | c.*30G>A | 3'UTR (SNP) | VAF 104/248 reads (42%) | called by muse, varscan2
- NFX1 | c.3039+63A>G | Intron (SNP) | VAF 24/137 reads (18%) | called by muse, varscan2
- NMT1 | c.884+34C>T | Intron (SNP) | VAF 74/155 reads (48%) | catalogued as rs772522385; called by muse, varscan2
- OBSCN | c.11660-1984G>T | Intron (SNP) | VAF 24/142 reads (17%) | called by muse, varscan2
- PHETA1 | c.*12C>T | 3'UTR (SNP) | VAF 43/104 reads (41%) | catalogued as rs775332423; called by muse, varscan2
- PJVK | chr2:178452631 G>T | 5'Flank (SNP) | VAF 108/262 reads (41%) | called by muse, varscan2
- PLEKHH1 | c.1435-78C>T | Intron (SNP) | VAF 16/95 reads (17%) | catalogued as rs1354244364; called by muse, varscan2
- PMVK | c.*87G>A | 3'UTR (SNP) | VAF 52/108 reads (48%) | catalogued as rs1021733942; called by muse, varscan2
- POLG | c.-17G>A | 5'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, varscan2
- POLR1F | c.397-26C>T | Intron (SNP) | VAF 56/126 reads (44%) | catalogued as rs369577528; called by muse, varscan2
- PRDM6 | c.*36T>A | 3'UTR (SNP) | VAF 86/166 reads (52%) | called by muse, varscan2
- PSD | c.-10C>T | 5'UTR (SNP) | VAF 48/214 reads (22%) | catalogued as rs750056553; called by muse, varscan2
- RAI14 | c.36+1268C>T | Intron (SNP) | VAF 130/343 reads (38%) | catalogued as rs755622799, COSV99461957; called by muse, varscan2
- RNF126 | c.444-23G>A | Intron (SNP) | VAF 40/94 reads (43%) | catalogued as rs373118509; called by muse, varscan2
- RPL28 | c.*3269G>A | 3'UTR (SNP) | VAF 119/279 reads (43%) | called by muse, varscan2
- SEMA5A | c.333+70G>C | Intron (SNP) | VAF 32/165 reads (19%) | called by muse, varscan2
- SF3A2 | c.199-21C>T | Intron (SNP) | VAF 64/146 reads (44%) | catalogued as rs1334682979; called by muse, varscan2
- SSPOP | n.9078G>T | RNA (SNP) | VAF 58/129 reads (45%) | called by muse, varscan2
- SYTL2 | c.2275-23G>A | Intron (SNP) | VAF 47/266 reads (18%) | called by muse, varscan2
- TGFB1I1 | c.13+30G>A | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, varscan2
- THRAP3 | c.*14C>T | 3'UTR (SNP) | VAF 73/153 reads (48%) | catalogued as rs773411849, COSV100454360; called by muse, varscan2
- TMEM273 | c.238+19G>A | Intron (SNP) | VAF 48/239 reads (20%) | catalogued as rs368180537; called by muse, varscan2
- TPTE | c.*24G>T | 3'UTR (SNP) | VAF 68/284 reads (24%) | catalogued as rs1344866226; called by muse, varscan2
- TRPA1 | c.1195-14A>T | Intron (SNP) | VAF 85/183 reads (46%) | called by muse, varscan2
- TRUB2 | c.317-16G>A | Intron (SNP) | VAF 58/186 reads (31%) | catalogued as rs376329657; called by muse, varscan2
- TYK2 | c.2908+50C>T | Intron (SNP) | VAF 56/118 reads (47%) | catalogued as rs531812472; called by muse, varscan2
- USP9X | c.*59T>C | 3'UTR (SNP) | VAF 56/114 reads (49%) | called by muse, varscan2
- VEZT | c.1832-1060G>A | Intron (SNP) | VAF 127/276 reads (46%) | catalogued as rs909806541; called by muse, varscan2
- ZNF516 | c.*35C>T | 3'UTR (SNP) | VAF 59/169 reads (35%) | catalogued as rs753416666, COSV101487213; called by muse, varscan2
- ZNF830 | c.*17G>T | 3'UTR (SNP) | VAF 18/147 reads (12%) | called by muse, varscan2
